Somatic mutation profile of tumor specimen 0DRE11 from CCDI case PBCGKW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,163 days).
Specimen 0DRE11: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5830ae2c-e9f7-4e6a-a5bc-b9a0d2d98a00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRE0L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2862606-70ec-4ecd-9223-abc0555dbc25

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNKSR2 | c.2513A>G p.N838S | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs942789183; called by muse, mutect2
- PITPNM1 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 36/688 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs183937953; called by muse, mutect2
- OR52K1 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 30/970 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2
- SMG7 | c.-78C>T | 5'UTR (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
